Somatic mutation profile of tumor specimen TCGA-BL-A5ZZ-01A (aliquot TCGA-BL-A5ZZ-01A-31D-A30E-08) from TCGA case TCGA-BL-A5ZZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.1 years (29,247 days).
Specimen TCGA-BL-A5ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7817219a-8381-4d67-a98f-323597b951e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A5ZZ-10A (Blood Derived Normal), aliquot TCGA-BL-A5ZZ-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f72c9c-7338-4a09-9159-8ca8f96b5c40

The open-access MAF lists 191 somatic variants for this specimen: 136 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 52, Nonsense Mutation 15, Frame Shift Del 6, Splice Site 4, Frame Shift Ins 2, Splice Region 2, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 28/121 reads (23%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1057518414, CM149465, COSV61804750, COSV61807046; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56194661; called by muse, mutect2, varscan2
- ACADSB | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV62550304; called by mutect2, varscan2
- ADAMTS16 | c.2996C>G p.S999* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV56979513, COSV99940616; called by muse, mutect2, varscan2
- AFF4 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54791477, COSV99534619; called by muse, mutect2, varscan2
- AGTR2 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV64156159; called by muse, mutect2, varscan2
- ANO9 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV60382386; called by muse, varscan2
- APOL3 | c.1180C>T p.Q394* (on ENST00000349314 / NM_145640.2; = p.Q323* on NM_014349.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/186 reads (22%) | catalogued as rs771847774, COSV100652035; called by muse, mutect2, varscan2
- ATXN2 | c.2045G>C p.R682T (on ENST00000550104; = p.R522T on NM_002973.4) | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66481259; called by muse, mutect2, varscan2
- BATF3 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV54657635; called by muse, mutect2, varscan2
- BCAS3 | c.1878G>A p.M626I (on ENST00000390652 / NM_001353144.2; = p.M611I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV66770087; called by muse, mutect2, varscan2
- BPTF | c.7978G>T p.E2660* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100074461; called by muse, varscan2
- C1orf94 | c.1136T>A p.L379Q (on ENST00000488417 / NM_001134734.2; = p.L189Q on NM_032884.5) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV64912972; called by muse, mutect2, varscan2
- CABIN1 | c.5144C>G p.S1715* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99572920; called by muse, mutect2, varscan2
- CASK | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as COSV59361602; called by muse, varscan2
- CEP135 | c.3076G>T p.E1026* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99954249; called by muse, mutect2, varscan2
- CEP57 | c.968A>G p.N323S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1266159669, COSV57687306; called by muse, mutect2, varscan2
- CKAP2 | c.1147A>G p.K383E (on ENST00000378037 / NM_001098525.2; = p.K382E on NM_018204.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV51620811; called by muse, mutect2, varscan2
- CRYBG1 | c.4079C>G p.S1360* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100954425; called by muse, mutect2, varscan2
- CRYBG1 | c.4993C>T p.H1665Y | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV64810501; called by muse, mutect2, varscan2
- CRYBG1 | c.5074C>T p.H1692Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs1394897926, COSV64810517; called by muse, mutect2, varscan2
- CYP11B2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750090886, COSV59994448; called by muse, mutect2, varscan2
- CYP24A1 | c.991-1G>A p.X331_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV53772859; called by muse, mutect2, varscan2
- DACT1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV60019387; called by muse, mutect2, varscan2
- DIDO1 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV56613677; called by muse, mutect2, varscan2
- DIDO1 | c.2334G>A p.V778= | Splice Region (SNP) | VAF 29/138 reads (21%) | catalogued as COSV56613697, COSV99825570; called by muse, mutect2, varscan2
- DYRK1B | c.1412-2A>T p.X471_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV59912855; called by muse, mutect2, varscan2
- EGR1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV53517964, COSV53518067; called by muse, mutect2, varscan2
- EIF5 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs750458635, COSV53684680; called by muse, mutect2, varscan2
- EPS8 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99842864; called by muse, mutect2, varscan2
- F7 | c.1220C>A p.P407Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60644977; called by muse, mutect2, varscan2
- FAT4 | c.7252C>A p.Q2418K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58671587; called by muse, mutect2, varscan2
- FLNA | c.6688G>T p.V2230L (on ENST00000369850 / NM_001110556.2; = p.V2222L on NM_001456.3) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV61037492, COSV61037727; called by muse, mutect2, varscan2
- FMR1NB | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782765066, COSV65071031; called by muse, mutect2, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs772301203; called by mutect2, varscan2
- GDF11 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs779013078, COSV57689229; called by muse, mutect2, varscan2
- GGTLC2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs372420836; called by muse, mutect2, varscan2
- GMIP | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs146115077; called by muse, mutect2, varscan2
- GPD2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756846628, COSV60090128; called by muse, mutect2, varscan2
- GPR174 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52131467; called by muse, mutect2, varscan2
- H1-2 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.902); catalogued as COSV59189752; called by muse, mutect2, varscan2
- HAO2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1009749302, COSV58037825; called by muse, mutect2, varscan2
- HELZ2 | c.7404C>G p.I2468M (on ENST00000467148 / NM_001037335.2; = p.I1899M on NM_033405.3) | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV64442448; called by muse, mutect2, varscan2
- IGF1 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61031522, COSV61033483, COSV61034106; called by muse, mutect2
- IGKV1-12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs764773736; called by muse, mutect2
- KCNH8 | c.2635C>T p.Q879* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100109150, COSV60458657; called by muse, mutect2, varscan2
- KCNJ8 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53715218; called by muse, mutect2, varscan2
- KDM6A | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV65039309; called by muse, varscan2
- KDM6A | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV65037160; called by muse, varscan2
- KDM6A | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV65037166, COSV65043191; called by muse, mutect2, varscan2
- KIAA1958 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); catalogued as rs1385935190, COSV61721644; called by muse, mutect2, varscan2
- KLHL17 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as rs761049058, COSV58530833; called by muse, mutect2, varscan2
- LMO7 | c.2566G>A p.E856K (on ENST00000357063; = p.E537K on NM_005358.5) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV58529844; called by muse, mutect2, varscan2
- MAGEA12 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV63294177; called by muse, mutect2, varscan2
- MAGT1 | c.50C>T p.A17V (on ENST00000618282 / NM_001367916.1; = p.A49V on NM_032121.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63780886; called by muse, mutect2, varscan2
- MAMDC2 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as rs749095478, COSV65858167; called by muse, mutect2, varscan2
- MAN2B1 | c.1918A>T p.T640S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55470049; called by muse, mutect2, varscan2
- MARCHF7 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 56/363 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52027190; called by muse, mutect2, varscan2
- MSH6 | c.4063A>G p.T1355A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV52274251; called by muse, mutect2, varscan2
- MTNR1A | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775674720, COSV56154968, COSV56156196; called by muse, mutect2, varscan2
- MTUS1 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV50550746; called by muse, varscan2
- MTUS1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50550760; called by muse, varscan2
- MXRA5 | c.1140G>C p.L380F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54223836; called by muse, mutect2, varscan2
- MYT1 | c.1601A>C p.K534T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV60501035; called by muse, mutect2
- NDUFB10 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746790349, COSV51909434; called by muse, mutect2, varscan2
- NEK4 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1237485089, COSV51778682, COSV51780933; called by muse, mutect2, varscan2
- NFAT5 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as COSV63025129; called by muse, mutect2, varscan2
- NIPA2 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV57405262; called by muse, mutect2, varscan2
- NOS1 | c.3532C>T p.R1178C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs77074921, COSV57606685; called by muse, mutect2
- NOS2 | c.1525_1526del p.K509Efs*65 | Frame Shift Del (DEL) | VAF 57/400 reads (14%) | catalogued as COSV58221767; called by mutect2, pindel, varscan2
- NR2E3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as COSV58907324; called by muse, mutect2, varscan2
- NRIP1 | c.3387G>A p.M1129I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV59655026; called by muse, mutect2, varscan2
- NUP188 | c.5246G>C p.R1749T | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV65330109; called by muse, mutect2, varscan2
- NYX | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100699387; called by muse, mutect2, varscan2
- OR5V1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65826339; called by muse, mutect2, varscan2
- PCDHA13 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1211665444, COSV56477740; called by muse, mutect2, varscan2
- PCDHB11 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781883051, COSV61309842; called by muse, mutect2, varscan2
- PCNX2 | c.3466A>G p.I1156V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV50782065; called by muse, mutect2, varscan2
- PCSK1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs763572977, COSV60733740, COSV60735290; called by muse, mutect2, varscan2
- PDE11A | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99611348; called by muse, mutect2, varscan2
- PDE3B | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56379686; called by muse, mutect2, varscan2
- PDE4DIP | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs782271941, COSV57674820; called by muse, mutect2, varscan2
- PDE6A | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54924632; called by muse, mutect2, varscan2
- PHOSPHO2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55865667; called by muse, mutect2, varscan2
- PLEKHH1 | c.1752C>G p.Y584* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV100232595, COSV100232864; called by muse, mutect2, varscan2
- PNOC | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57283006, COSV57284143; called by muse, varscan2
- PNOC | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57283014; called by muse, varscan2
- PSMD9 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761768941, COSV55838872; called by muse, mutect2, varscan2
- PTCHD3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.982); catalogued as rs775804385, COSV71256287; called by muse, mutect2, varscan2
- RABGGTA | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs745370644, COSV52861794, COSV99252957; called by muse, mutect2, varscan2
- RC3H1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1160885450, COSV51197862; called by muse, mutect2, varscan2
- RPL3L | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV51905212; called by muse, varscan2
- RYR2 | c.6883G>T p.G2295* | Nonsense Mutation (SNP) | VAF 52/211 reads (25%) | catalogued as COSV100769001, COSV63713327; called by muse, mutect2, varscan2
- SAMD4B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100080350, COSV58750100, COSV58753067; called by muse, mutect2, varscan2
- SDCBP | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs756701491, COSV99232608; called by muse, mutect2, varscan2
- SF3B1 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59206526; called by muse, mutect2, varscan2
- SIGLEC10 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs750650378, COSV59478898; called by muse, mutect2, varscan2
- SLC16A4 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63915937; called by muse, mutect2, varscan2
- SLC2A4RG | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs747909927, COSV55507359; called by mutect2, varscan2
- SLC45A1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs753204552, COSV57092942; called by muse, mutect2, varscan2
- SLX4 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV53560854; called by muse, mutect2, varscan2
- SP140 | c.1556A>T p.Q519L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV59446385; called by muse, mutect2, varscan2
- SPPL2B | c.1647G>T p.Q549H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.359); catalogued as COSV101476102; called by muse, mutect2
- SYCP1 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV65694561; called by muse, mutect2, varscan2
- TACC2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs758543512, COSV57746181; called by muse, mutect2, varscan2
- TBC1D32 | c.2680-1G>C p.X894_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV51536263; called by muse, mutect2, varscan2
- THAP7 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs754681452, COSV53145140; called by muse, mutect2, varscan2
- TMEM107 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.496); catalogued as COSV57100780; called by muse, mutect2, varscan2
- TMEM131L | c.4653C>G p.I1551M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV53641040; called by muse, mutect2, varscan2
- TOPBP1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53432410; called by muse, mutect2, varscan2
- TRPS1 | c.2510A>T p.H837L (on ENST00000220888 / NM_001330599.2; = p.H850L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV55226736; called by muse, mutect2, varscan2
- TSPAN31 | c.447C>A p.I149= | Splice Region (SNP) | VAF 31/141 reads (22%) | catalogued as COSV57275601; called by muse, mutect2, varscan2
- TUBB | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV58357275; called by muse, mutect2, varscan2
- UBA5 | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV53903946; called by muse, mutect2, varscan2
- UBASH3A | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1476479215, COSV52310479; called by muse, mutect2, varscan2
- VPS13C | c.4886C>G p.A1629G (on ENST00000644861 / NM_020821.3; = p.A1586G on NM_017684.5) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV51121587; called by muse, mutect2, varscan2
- WDR62 | c.3447+1G>A p.X1149_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as rs369923535; called by muse, mutect2, varscan2
- XIAP | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63021595; called by muse, mutect2, varscan2
- XIRP2 | c.8892C>G p.N2964K (on ENST00000628543; = p.N3139K on NM_152381.6) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54682772, COSV54692150; called by muse, mutect2, varscan2
- YTHDC2 | c.2792A>G p.E931G | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs754664071, COSV50736620; called by muse, mutect2, varscan2
- ZEB2 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.979); catalogued as COSV57951447; called by muse, mutect2, varscan2
- ZHX2 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as COSV58710191; called by muse, mutect2, varscan2
- ZMAT1 | c.1669T>G p.S557A | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV65657740; called by muse, mutect2, varscan2
- ZNF292 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100370121; called by muse, mutect2, varscan2
- ZNF687 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1168728655, COSV55014728; called by muse, mutect2, varscan2
- ZRANB3 | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV51493970; called by muse, mutect2, varscan2
- ZSCAN9 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1256834712, COSV52849203; called by muse, mutect2, varscan2
- ARID1A | c.4689dup p.M1564Hfs*8 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- DMAC2L | c.542del p.N181Ifs*15 | Frame Shift Del (DEL) | VAF 51/161 reads (32%) | called by mutect2, pindel, varscan2
- GPR179 | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1299del p.K433Nfs*5 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- KMT2D | c.5138_5139del p.G1713Afs*21 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- NUP133 | c.1043dup p.N348Kfs*3 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- PSMC6 | c.383_384del p.E128Gfs*7 (on ENST00000612399; = p.E114Gfs*7 on NM_002806.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/175 reads (26%) | called by pindel, varscan2
- ADAMTSL3 | c.1248C>T p.F416= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV54436251; called by muse, mutect2, varscan2
- ADCY5 | c.3564G>A p.V1188= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100568500, COSV59194122; called by muse, mutect2, varscan2
- AKR1C2 | c.630C>T p.D210= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1213125602, COSV101060421; called by muse, mutect2, varscan2
- ALX1 | c.621T>C p.Y207= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1279056863, COSV57491149, COSV57492960; called by muse, mutect2, varscan2
- ANTXR1 | c.1131G>A p.T377= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs111544315; called by muse, mutect2, varscan2
- ARMCX2 | c.441G>A p.E147= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV57529219; called by muse, mutect2, varscan2
- ATP2A2 | c.819C>T p.I273= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV58042319; called by muse, mutect2, varscan2
- AXDND1 | c.1626C>G p.L542= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV62639657; called by muse, mutect2, varscan2
- CARMIL2 | c.1533G>A p.V511= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs769055095, COSV58023067; called by muse, mutect2, varscan2
- CDC42BPB | c.1434C>T p.L478= | Silent (SNP) | VAF 81/255 reads (32%) | catalogued as COSV63473868, COSV63474972; called by muse, mutect2, varscan2
- CNTNAP4 | c.3483G>T p.A1161= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56664987; called by muse, mutect2, varscan2
- COL22A1 | c.2931C>T p.L977= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1467340427, COSV57323169; called by muse, mutect2, varscan2
- COL27A1 | c.666G>T p.T222= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as COSV61921539; called by muse, mutect2, varscan2
- CRYL1 | c.561G>A p.Q187= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV53416261; called by muse, mutect2, varscan2
- DAXX | c.1662G>A p.E554= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV56466597; called by muse, mutect2, varscan2
- DENND2A | c.282G>A p.E94= | Silent (SNP) | VAF 74/236 reads (31%) | catalogued as rs1563171487, COSV52047780; called by muse, mutect2, varscan2
- DOC2A | c.681G>A p.A227= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs769227502, COSV58750545; called by muse, mutect2, varscan2
- DSC1 | c.174G>C p.S58= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs767775240, COSV57141767; called by muse, mutect2, varscan2
- FAM149A | c.1521C>T p.H507= (on ENST00000356371 / NM_001367768.2; = p.H216= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs1316932163, COSV57025688; called by muse, mutect2, varscan2
- FBXW9 | c.1371T>A p.A457= (on ENST00000587955; = p.A437= on NM_032301.3) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV66709276; called by muse, mutect2, varscan2
- FGG | c.1284G>A p.L428= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV60194526, COSV60195275; called by muse, mutect2, varscan2
- GEMIN7 | c.336T>C p.G112= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV54319172; called by muse, mutect2, varscan2
- GKN2 | c.387C>T p.D129= | Silent (SNP) | VAF 81/223 reads (36%) | catalogued as rs766539836, COSV61030890, COSV61031367; called by muse, mutect2, varscan2
- GRM1 | c.2646G>A p.G882= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV51108946, COSV51172338; called by muse, mutect2, varscan2
- HPS6 | c.48C>T p.F16= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100154824; called by muse, mutect2
- LCP1 | c.564C>T p.F188= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV59939375; called by muse, mutect2, varscan2
- MCUR1 | c.819A>G p.L273= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1251543436, COSV64846604; called by muse, mutect2, varscan2
- MORN5 | c.435C>T p.N145= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs536933863, COSV65648421; called by muse, mutect2, varscan2
- MUC2 | c.2367C>T p.P789= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs767119745; called by muse, mutect2
- NKAP | c.376C>T p.L126= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs1331436948, COSV65055930; called by muse, mutect2, varscan2
- NOB1 | c.960C>T p.R320= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs764369537, COSV52060804; called by muse, mutect2, varscan2
- NUTM2F | c.1164G>A p.E388= | Silent (SNP) | VAF 116/237 reads (49%) | catalogued as COSV53555368; called by muse, mutect2, varscan2
- PCDHA13 | c.270C>T p.I90= | Silent (SNP) | VAF 81/394 reads (21%) | catalogued as rs782086663, COSV56477733; called by muse, mutect2, varscan2
- PHF12 | c.316C>A p.R106= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV52018035, COSV52021104; called by muse, mutect2, varscan2
- PLD3 | c.966C>T p.I322= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV52519069; called by muse, mutect2, varscan2
- PLEKHA5 | c.1038G>C p.L346= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV54694055; called by muse, mutect2, varscan2
- PTPN22 | c.1521C>T p.H507= (on ENST00000359785 / NM_001193431.2; = p.H452= on NM_012411.5) | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV63084329; called by muse, mutect2, varscan2
- PTPRF | c.4728C>T p.I1576= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV63442490; called by muse, mutect2, varscan2
- RAB33B | c.45C>T p.S15= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1381336631, COSV59777073; called by muse, mutect2, varscan2
- RBL1 | c.3117A>T p.A1039= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV60328280; called by muse, mutect2, varscan2
- RELB | c.1044C>T p.F348= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV55508330; called by muse, mutect2, varscan2
- RELB | c.1137C>T p.V379= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV55508338; called by muse, mutect2, varscan2
- SH3GL2 | c.252A>G p.P84= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs574677341, COSV66047683; called by muse, mutect2, varscan2
- SLC46A2 | c.873C>T p.I291= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV65289550; called by muse, mutect2, varscan2
- SNRPD2 | c.216G>A p.E72= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV50003487; called by muse, mutect2, varscan2
- SRRM4 | c.501G>A p.K167= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV57408592, COSV57409598; called by muse, mutect2, varscan2
- TSNARE1 | c.228C>T p.A76= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56170766; called by muse, mutect2, varscan2
- TTR | c.354C>T p.N118= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs11541797; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.4002C>T p.I1334= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV52132379; called by muse, mutect2, varscan2
- UMOD | c.1029G>A p.S343= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs375846119, COSV56773517, COSV56778852; called by muse, mutect2, varscan2
- VCAN | c.627C>T p.P209= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV54096889; called by muse, mutect2, varscan2
- ZSWIM4 | c.624C>T p.I208= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54319260; called by muse, mutect2, varscan2
- MGAM | c.4618+10754A>G | Intron (SNP) | VAF 22/121 reads (18%) | catalogued as rs546149133, COSV72073624; called by muse, mutect2, varscan2
- MIR587 | n.30G>A | RNA (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- SH3BP4 | c.-1G>A | 5'UTR (SNP) | VAF 12/63 reads (19%) | catalogued as rs538568414, COSV100749065; called by muse, mutect2, varscan2
